Somatic mutation profile of cancer-model specimen HCM-CSHL-0250-C50-85C (3D Organoid, passage 16; aliquot HCM-CSHL-0250-C50-85C-01D-A82H-36), derived from the primary tumor of HCMI case HCM-CSHL-0250-C50, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pleomorphic carcinoma; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 60.3 years (22,028 days).
Specimen HCM-CSHL-0250-C50-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 16.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8099276b-0b3d-437f-bef0-3c83d83103bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0250-C50-10A (Blood Derived Normal), aliquot HCM-CSHL-0250-C50-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9c93c01-ab6a-4bb7-b31a-c9e65aefc289

The open-access MAF lists 56 somatic variants for this specimen: 41 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Frame Shift Ins 4, Nonsense Mutation 3, In Frame Del 2, In Frame Ins 1, 3'Flank 1, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 269/270 reads (100%) | hotspot (GDC flag); catalogued as COSV55726950; called by muse, mutect2, varscan2
- FOXA1 | c.798C>G p.F266L | Missense Mutation (SNP) | VAF 30/753 reads (4%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV51643681, COSV51647960; called by muse, mutect2
- ASXL3 | c.5851T>C p.S1951P | Missense Mutation (SNP) | VAF 129/244 reads (53%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1414083031; called by muse, mutect2, varscan2
- DDX25 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 132/196 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs1431146048; called by muse, mutect2, varscan2
- DRD2 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV60757879; called by muse, mutect2, varscan2
- FNTA | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 95/433 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1411881847; called by muse, mutect2, varscan2
- GRM4 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 33/515 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1012258054; called by muse, mutect2
- KLHDC8A | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 191/591 reads (32%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs371072469; called by muse, mutect2, varscan2
- MYH1 | c.4691G>A p.R1564H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as rs750693945, COSV56852871; called by muse, mutect2, varscan2
- OR2G3 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 108/575 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1389655790, COSV60681606; called by muse, mutect2, varscan2
- PCSK7 | c.283C>T p.H95Y | Missense Mutation (SNP) | VAF 55/743 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.01); catalogued as COSV100309371; called by muse, mutect2
- PGLYRP3 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 121/831 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs763623473; called by muse, mutect2, varscan2
- PLA2G4D | c.1792C>T p.L598F | Missense Mutation (SNP) | VAF 193/590 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs765087738, COSV99299677; called by muse, mutect2
- PRDM15 | c.3178C>G p.P1060A | Missense Mutation (SNP) | VAF 204/309 reads (66%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.656); catalogued as COSV54157530; called by muse, mutect2, varscan2
- SRD5A1 | c.214G>T p.A72S | Missense Mutation (SNP) | VAF 233/940 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0.014); catalogued as rs776185174; called by mutect2, varscan2
- TDRD6 | c.3314A>G p.D1105G | Missense Mutation (SNP) | VAF 27/246 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.2); catalogued as rs1478497474; called by muse, mutect2, varscan2
- UNC45B | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 127/271 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.503); catalogued as rs1354715000, COSV52096263; called by muse, mutect2, varscan2
- ZNF831 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 316/457 reads (69%) | SIFT tolerated (0.45); PolyPhen benign (0.038); catalogued as rs200422985; called by muse, mutect2, varscan2
- CHTF18 | c.2657G>A p.G886E | Missense Mutation (SNP) | VAF 250/706 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2
- CLINT1 | c.1216G>T p.G406C | Missense Mutation (SNP) | VAF 195/659 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CUX1 | c.2902G>T p.E968* | Nonsense Mutation (SNP) | VAF 123/194 reads (63%) | called by muse, mutect2, varscan2
- DRGX | c.17G>A p.C6Y | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ERBB2 | c.2092_2094del p.E698del | In Frame Del (DEL) | VAF 104/229 reads (45%) | called by mutect2, pindel, varscan2
- FASN | c.1641_1643del p.D548del | In Frame Del (DEL) | VAF 101/218 reads (46%) | called by pindel, varscan2
- GRIN2C | c.68C>A p.P23Q | Missense Mutation (SNP) | VAF 240/460 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- HSPA5 | c.1461_1462dup p.P488Lfs*17 | Frame Shift Ins (INS) | VAF 104/239 reads (44%) | called by mutect2, pindel, varscan2
- KDM6A | c.3284dup p.W1096Vfs*7 | Frame Shift Ins (INS) | VAF 38/114 reads (33%) | called by mutect2, pindel, varscan2
- LATS2 | c.3182C>G p.A1061G | Missense Mutation (SNP) | VAF 56/437 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRRC7 | c.439G>A p.E147K (on ENST00000651989 / NM_001370785.2; = p.E114K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.06); PolyPhen benign (0.065); called by mutect2, varscan2
- MAGEB5 | c.799A>G p.K267E | Missense Mutation (SNP) | VAF 117/269 reads (43%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- NACA2 | c.12A>T p.E4D | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.093); called by muse, mutect2
- OCLN | c.532G>A p.V178M | Missense Mutation (SNP) | VAF 46/604 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.069); called by muse, mutect2
- PTPRQ | c.3859C>G p.P1287A (on ENST00000616559; = p.P1245A on NM_001145026.2) | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2
- RUNX1 | c.293del p.P98Qfs*8 (on ENST00000344691 / NM_001001890.3; = p.P125Qfs*8 on NM_001754.5) | Frame Shift Del (DEL) | VAF 98/378 reads (26%) | called by mutect2, pindel, varscan2
- SERPINB9 | c.54dup p.L19Tfs*5 | Frame Shift Ins (INS) | VAF 153/305 reads (50%) | called by mutect2, pindel, varscan2
- SLIT1 | c.793+1G>A p.X265_splice | Splice Site (SNP) | VAF 42/279 reads (15%) | called by muse, mutect2, varscan2
- SNTG1 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 29/209 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- STAT3 | c.1438_1441dup p.N481Ifs*69 | Frame Shift Ins (INS) | VAF 75/219 reads (34%) | called by mutect2, pindel, varscan2
- TCERG1L | c.528G>A p.W176* | Nonsense Mutation (SNP) | VAF 17/352 reads (5%) | called by muse, mutect2
- TEX47 | c.578_580dup p.T193dup | In Frame Ins (INS) | VAF 81/334 reads (24%) | called by mutect2, pindel, varscan2
- ZCCHC3 | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 291/440 reads (66%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- C4orf51 | c.402G>T p.P134= | Silent (SNP) | VAF 40/40 reads (100%) | called by mutect2, varscan2
- DNAJC13 | c.5109A>G p.Q1703= | Silent (SNP) | VAF 7/131 reads (5%) | catalogued as rs1427423355, COSV53453638; called by muse, mutect2
- FGF23 | c.705C>T p.H235= | Silent (SNP) | VAF 77/507 reads (15%) | catalogued as rs1183278014, COSV52977546; called by muse, mutect2, varscan2
- FMO2 | c.1104C>T p.C368= | Silent (SNP) | VAF 182/581 reads (31%) | catalogued as rs568414940; called by muse, mutect2, varscan2
- FOXK1 | c.480G>C p.L160= | Silent (SNP) | VAF 72/525 reads (14%) | catalogued as rs760256909; called by muse, mutect2, varscan2
- GRK2 | c.2013C>T p.P671= | Silent (SNP) | VAF 87/594 reads (15%) | catalogued as rs781718935; called by muse, mutect2, varscan2
- KCNG4 | c.405G>T p.L135= | Silent (SNP) | VAF 180/332 reads (54%) | called by mutect2, varscan2
- KIF4A | c.210G>A p.A70= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as rs755499983; called by muse, mutect2, varscan2
- LRRK1 | c.300G>T p.L100= | Silent (SNP) | VAF 18/416 reads (4%) | called by muse, mutect2
- NDST2 | c.1947T>C p.N649= | Silent (SNP) | VAF 73/221 reads (33%) | catalogued as rs770612253; called by muse, mutect2, varscan2
- RGS3 | c.2610G>A p.G870= (on ENST00000350696 / NM_001282923.2; = p.G589= on NM_130795.4) | Silent (SNP) | VAF 115/416 reads (28%) | called by muse, mutect2
- SOX18 | c.81G>T p.G27= | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- STAB2 | c.2922G>A p.S974= | Silent (SNP) | VAF 77/248 reads (31%) | catalogued as rs150100761; called by muse, mutect2, varscan2
- TEX38 | c.543T>C p.N181= | Silent (SNP) | VAF 10/304 reads (3%) | called by muse, mutect2
- MIR1915 | chr10:21495795 G>T | 3'Flank (SNP) | VAF 33/700 reads (5%) | catalogued as COSV101008156; called by muse, mutect2
